Surgical pathology report (de-identified scan), TCGA case TCGA-A6-5659, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-5659-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cecal cancer

GROSS DESCRIPTION

Received fresh for tissue procurement labelled "right colon" is a previously unopened 25 cm segment of proximal right colon with attached 21 cm of distal ileum surfaced by smooth to slightly scabrous tan-pink serosa with a copious amount of attached mesocolon, mesentery, and unremarkable omentum. No appendix is identified grossly. The proximal and distal margins measure 4.5 and 10.2 cm in circumference respectively. On opening, there is a moderately well-circumscribed, 5.0 x 4.2 cm rubbery tan-white-red tumor mass located 3.5 cm distal to the ileocecal valve. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. On sectioning, the tumor measures up to 0.8 cm in thickness, grossly extending into muscularis to within 0.15 cm of the inked free radial serosal surface (see blocks 2-4). Two additional sessile rubbery pale tan polypoid lesions measuring 0.4 and 1.0 cm in greatest dimension are present 8 and 2 cm distal to the aforementioned tumor (see blocks 6 and 7 respectively). The ileal and remaining uninvolved colonic mucosa are unremarkable glistening tan-pink with regular folds and the walls average 0.5 cm in thickness. Multiple soft to slightly rubbery tan-pink tissues in keeping with lymph nodes measuring up to

1.4 cm in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 15 blocks as labelled. RS-15.

BLOCK SUMMARY: 1 - proximal and distal margins; 2-4 - tumor full-thickness to inked free radial serosal surface; 5 - tumor to normal; 6 - small additional polypoid lesion; 7 - bisected larger additional polypoid lesion; 8 - random ileum; 9 - ICV; 10 - random colon; 11-12 - eight whole lymph nodes per cassette; 13 - s whole lymph nodes; 14-15 - five whole lymph nodes per cassette.

MICROSCOPIC DESCRIPTION

Histologic type: Invasive adenocarcinoma, not otherwise specified.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Tumor invades into muscularis propria, no invasion into pericolonic fat is identified and the serosal surface is negative for tumor (pT2).

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Not truly applicable, but the serosal surface is negative for tumor.

[page 2 of 2]
Distance of tumor from closest margin: 20 cm from distal margin
Vascular invasion: Not identified.
Regional lymph nodes (pN): Twenty-six lymph nodes are dissected from the specimen. They are all negative for metastatic tumor (pN0).
Non-lymph node pericolonic tumor: Not identified.
Distant metastasis (pM): Could not evaluate, pMX.
Other findings: One tubular adenoma is identified and one serrated adenoma is identified. Random sections of colon and small intestine are unremarkable.

5x1, 3260F

DIAGNOSIS

- A. Colon, right, ileocelectomy:
Invasive adenocarcinoma, moderately differentiated, invasive into muscularis propria (pT2).
Twenty-six lymph nodes negative for metastatic tumor (pN0).
One tubular adenoma and one serrated adenoma.
See Microscopic description.
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 08f0680a-e4db-40b5-8065-cc6fe745238a (TCGA-A6-5659.16172149-A834-4F41-A786-5D87A69FC65C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).